Somatic mutation profile of tumor specimen 0DR6YG from CCDI case PBCGCG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (147 days).
Specimen 0DR6YG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f02a793-8224-4c97-b8cb-7937b101c4bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6Y6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47c38dc6-5be6-4cf5-8358-8cb95935ce26

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNHD1 | c.12241C>T p.H4081Y | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.377); called by muse, mutect2
- SMPD1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 20/714 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- SFTPB | c.846C>T p.S282= | Silent (SNP) | VAF 40/894 reads (4%) | catalogued as rs1234243117, COSV60893442; called by muse, mutect2
